Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A1ED, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A1ED-01A (Primary Tumor).

[page 1 of 4]
Carcinoma, hepatocellular, NOS 8170/3

Site Code: Liver C22-0 1/19/11 JW

Patient Key:
Surgical date:

TISSUE DESCRIPTION:

A1 A2 A3 B1 B2 B3 B4 Portion liver segments V and VI (200 grams; 3.6 x 3.5 x 3.2 cm) and separately submitted gallbladder (10.0 x 5.0 x 3.0 cm).

DIAGNOSIS:

Liver, portion segments V and VI, resection: Well differentiated (grade 1 of 4) hepatocellular carcinoma forming a well demarcated and irregular-shaped subcapsular nodule (3.6 x 3.5 x 3.2 cm). The surgical margins are negative (closest is 1.5 cm).

Comment: The background liver is noncirrhotic. In cytochemical stains of the tumor mass using tissue block B4, there is a loss of normal reticulin architecture within the neoplasm supporting the diagnosis of hepatocellular carcinoma. The presence of pigment/hemorrhage within the lesion is likely reflective of the previous needle biopsy (outside material dated --

Gallbladder, cholecystectomy: Acute and chronic cholecystitis with cholelithiasis containing multiple (12) mixed stones ranging in size from 0.2 cm to 1.1 cm in greatest dimension. One of the stones is situated in the cystic duct near an area of stricture (0.5 cm in diameter).

PRELIMINARY FROZEN SECTION CONSULTATION:

Favor focal nodular hyperplasia. HOLD OVER for permanent sections.

[page 2 of 4]
Patient Key.
Surgical date:

TISSUE DESCRIPTION:

A1 A2 A3 B1 B2 B3 B4 Portion liver segments V and VI (200 grams; 3.6 x 3.5 x 3.2 cm) and separately submitted gallbladder (10.0 x 5.0 x 3.0 cm).

DIAGNOSIS:

Liver, portion segments V and VI, resection: Well differentiated (grade 1 of 4) hepatocellular carcinoma forming a well demarcated and irregular-shaped subcapsular nodule (3.6 x 3.5 x 3.2 cm). The surgical margins are negative (closest is 1.5 cm).

Comment: The background liver is noncirrhotic. In cytochemical stains of the tumor mass using tissue block B4, there is a loss of normal reticulin architecture within the neoplasm supporting the diagnosis of hepatocellular carcinoma. The presence of pigment/hemorrhage within the lesion is likely reflective of the previous needle biopsy (outside material dated

Gallbladder, cholecystectomy: Acute and chronic cholecystitis with cholelithiasis containing multiple (12) mixed stones ranging in size from 0.2 cm to 1.1 cm in greatest dimension. One of the stones is situated in the cystic duct near an area of stricture (0.5 cm in diameter).

PRELIMINARY FROZEN SECTION CONSULTATION:

Favor focal nodular hyperplasia. HOLD OVER for permanent sections.

[page 3 of 4]
Liver • Digestive System CAP Approved

* Data elements **with asterisks** are **not required** for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management. Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen.

LIVER: Resection

Patient name: *(to be de-identified)*

Surgical pathology number:

MACROSCOPIC**Specimen Type**

- ☒ Right lobectomy
☐ Extended right lobectomy
☐ Medial segmentectomy
☐ Left lateral segmentectomy
☐ Total left lobectomy
☐ Explanted liver
☐ Other (specify): _____
☐ Not specified

Focality

- ☒ Solitary (specify location): seg. IV, VI
☐ Multiple (specify location): _____

Tumor Size

Greatest dimension: 2.6 cm

*Additional dimensions: 2.5 x 2 cm

☐ Cannot be determined (see Comment)

MICROSCOPIC**Histologic Type**

- ☒ Hepatocellular carcinoma
☐ Fibrolamellar hepatocellular carcinoma variant (specify): _____
☐ Combined hepatocellular and cholangiocarcinoma
☐ Cholangiocarcinoma, intrahepatic
☐ Bile duct cystadenocarcinoma
☐ Undifferentiated carcinoma
☐ Other (specify): _____
☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
☐ GX: Cannot be assessed
☒ GI: Well differentiated
☐ GII: Moderately differentiated
☐ GIII: Poorly differentiated
☐ GIV: Undifferentiated/anaplastic
☐ Other (specify): _____

[page 4 of 4]
Pathologic Staging (pTNM)

Primary Tumor (pT)

- ☐ pTX: Cannot be assessed
☒ pT0: No evidence of primary tumor
☒ pT1: Solitary tumor with no vascular invasion
☐ pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
☐ pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)
☐ pT4: Tumor(s) with direct invasion of adjacent organs other than the gallbladder or perforation of visceral peritoneum

Regional Lymph Nodes (pN)

- ☒ pNX: Cannot be assessed
☐ pN0: No regional lymph node metastasis
☐ pN1: Regional lymph node metastasis

Specify: Number examined: ____

Number involved: ____

Distant Metastasis (pM)

- ☒ pMX: Cannot be assessed
☐ pM1: Distant metastasis

*Specify site(s), if known: _____

Margins (check all that apply)

Parenchymal Margin

- ☐ Cannot be assessed
☒ Uninvolved by invasive carcinoma *15.0*
Distance of invasive carcinoma from closest margin: ____ mm
Specify margin: _____

☐ Involved by invasive carcinoma

Bile Duct Margin (Cholangiocarcinoma Only)

- ☒ Cannot be assessed
☐ Uninvolved by invasive carcinoma
* ☐ Carcinoma in situ absent
* ☐ Carcinoma in situ present
☐ Involved by invasive carcinoma

Other Margin

Specify margin: _____

- ☐ Cannot be assessed
☐ Uninvolved by invasive carcinoma
☐ Involved by invasive carcinoma

***Venous (Large Vessel) Invasion (V)**

- * ☐ Absent
* ☐ Present
* ☒ Indeterminate

***Additional Pathologic Findings (check all that apply)**

- * ☐ None identified
* ☐ Hepatocellular dysplasia
* ☐ Ductal dysplasia
* ☐ Cirrhosis/fibrosis
* ☐ Iron overload
* ☐ Hepatitis (specify type): _____
* ☒ Other (specify): *non-cirrhotic*

Source: NCI Genomic Data Commons file 17c5ca09-996a-4a7b-a338-8afbf6d9301c (TCGA-DD-A1ED.6C4C27E3-EB96-48E4-BDF8-6E93C1557707.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).